Somatic mutation profile of tumor specimen TCGA-FD-A6TC-01A (aliquot TCGA-FD-A6TC-01A-21D-A339-08) from TCGA case TCGA-FD-A6TC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 79.3 years (28,963 days).
Specimen TCGA-FD-A6TC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e47dddc-70bb-4e03-afba-fe55deec6414.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A6TC-10A (Blood Derived Normal), aliquot TCGA-FD-A6TC-10A-21D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cae8acb4-b657-435d-94e3-da6689dcd122

The open-access MAF lists 1,072 somatic variants for this specimen: 763 protein-altering or splice-affecting, 281 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 668, Silent 281, Nonsense Mutation 69, Intron 10, Splice Site 10, Frame Shift Del 9, RNA 7, 3'UTR 5, 5'UTR 3, 3'Flank 2, In Frame Del 2, Translation Start Site 1.

Variants (750 of 1,072; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.5645C>G p.S1882* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as rs80358785, CM056302, CM980241, COSV101203821, COSV66450717; ClinVar: risk factor / pathogenic; called by muse, mutect2, varscan2
- GLA | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 21/166 reads (13%) | catalogued as rs727503949, CM940860; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.14586A>G p.I4862M | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1558481148, COSV63685679; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 16/24 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912652, CM900213, COSV52684909, COSV52740428, COSV52828352; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAAS | c.1015G>C p.D339H | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs140920186; called by muse, mutect2, varscan2
- AAAS | c.168G>C p.K56N | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV52932969; called by muse, mutect2, varscan2
- ABCB4 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV55935423, COSV55937530; called by muse, mutect2, varscan2
- ABCC1 | c.3407C>T p.S1136F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV60685881; called by muse, mutect2, varscan2
- ABCG4 | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777625706, COSV56643618; called by muse, mutect2, varscan2
- ABHD10 | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs1430585565, COSV56325168; called by muse, mutect2, varscan2
- ABLIM1 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs964169552, COSV53306187, COSV53316098; called by muse, mutect2
- AC025165.3 | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs747664076, COSV55744184; called by muse, mutect2, varscan2
- ACACB | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV58134677; called by muse, mutect2, varscan2
- ACAD10 | c.3005C>T p.S1002F | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV58156804; called by muse, varscan2
- ADAMTS9 | c.4765G>A p.E1589K | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.322); catalogued as rs566603785, COSV55781049; called by muse, mutect2, varscan2
- ADAMTS9 | c.4481G>A p.R1494Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as rs200540718, COSV55781058; called by muse, mutect2, varscan2
- ADCY5 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV59197885; called by muse, varscan2
- ADCY8 | c.2803G>C p.E935Q | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.057); catalogued as COSV53907668; called by muse, mutect2, varscan2
- ADD1 | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV99295884; called by muse, mutect2, varscan2
- ADGRA1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as rs778790324; called by muse, varscan2
- ADGRA3 | c.1086-1G>C p.X362_splice | Splice Site (SNP) | VAF 8/59 reads (14%) | catalogued as COSV51563172; called by muse, mutect2, varscan2
- ADRA2A | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54527891; called by muse, mutect2, varscan2
- AGA | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV52806280; called by muse, mutect2, varscan2
- AGAP1 | c.1876G>C p.D626H (on ENST00000304032 / NM_001037131.3; = p.D573H on NM_014914.5) | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58326210; called by muse, mutect2, varscan2
- AGPAT2 | c.779C>G p.S260C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760141111, COSV58247674; called by muse, mutect2, varscan2
- AGTPBP1 | c.3328C>A p.Q1110K (on ENST00000357081 / NM_001330701.2; = p.Q1070K on NM_015239.2) | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV61271700; called by muse, mutect2, varscan2
- AGTPBP1 | c.2435C>G p.S812* (on ENST00000357081 / NM_001330701.2; = p.S772* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 31/124 reads (25%) | catalogued as COSV100429130; called by muse, mutect2, varscan2
- AHI1 | c.2804G>T p.G935V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as COSV55627778; called by muse, mutect2, varscan2
- AIFM1 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs765245709, COSV54852558, COSV54854675; called by muse, varscan2
- AJM1 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as rs1276043391, COSV56032983; called by muse, mutect2, varscan2
- ALAD | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.122); catalogued as COSV52958867; called by muse, mutect2, varscan2
- ALAD | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52958886; called by muse, mutect2, varscan2
- ALG12 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | PolyPhen possibly damaging (0.657); catalogued as rs911437496, COSV58207097; called by muse, mutect2, varscan2
- AMER2 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV63436019; called by muse, mutect2, varscan2
- AMPD1 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as COSV62416211; called by muse, mutect2, varscan2
- ANK3 | c.11783A>G p.K3928R | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as COSV55057917; called by muse, mutect2, varscan2
- ANK3 | c.10075G>A p.E3359K | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV55057929; called by muse, mutect2, varscan2
- ANKAR | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.545); catalogued as COSV55612787; called by muse, mutect2, varscan2
- ANKRD11 | c.4304G>C p.R1435T | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV56360949; called by muse, mutect2, varscan2
- ANKRD24 | c.628C>G p.Q210E | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as COSV53670455; called by muse, mutect2, varscan2
- ANKS1B | c.2333C>G p.S778W | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as CM142848, COSV61341690, COSV61351459; called by muse, mutect2, varscan2
- AP3B2 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.614); catalogued as COSV55609586; called by muse, mutect2, varscan2
- APAF1 | c.1417C>G p.L473V (on ENST00000551964 / NM_181861.2; = p.L462V on NM_001160.3) | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.147); catalogued as COSV59664072; called by muse, mutect2, varscan2
- APLN | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777914054, COSV56741928; called by muse, varscan2
- APOB | c.9955G>A p.D3319N | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.986); catalogued as COSV51935282; called by muse, mutect2, varscan2
- AQP2 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as rs1363342807, COSV99550679; called by muse, mutect2
- ARFGEF1 | c.5265G>C p.L1755F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV51608751; called by muse, mutect2, varscan2
- ARFGEF2 | c.4467G>T p.W1489C | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV64211998, COSV64212324; called by muse, mutect2
- ARHGAP20 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.88); catalogued as COSV52811289; called by muse, mutect2, varscan2
- ARHGAP20 | c.453G>T p.M151I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV52811311; called by muse, mutect2, varscan2
- ARHGAP30 | c.2983C>G p.L995V (on ENST00000368013 / NM_001025598.2; = p.L784V on NM_181720.3) | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV63516543; called by muse, mutect2, varscan2
- ARHGAP30 | c.310C>G p.P104A | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63516551; called by muse, mutect2, varscan2
- ARHGAP6 | c.1013C>G p.S338* | Nonsense Mutation (SNP) | VAF 33/72 reads (46%) | catalogued as COSV100272111; called by muse, mutect2, varscan2
- ARHGEF7 | c.1155C>A p.F385L (on ENST00000375741 / NM_001113511.2; = p.F207L on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs761301621, COSV54543321; called by muse, mutect2, varscan2
- ARID1B | c.1579C>T p.Q527* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as rs1554256688, COSV99266497; called by muse, mutect2, varscan2
- ARL14EP | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV56342805; called by muse, mutect2, varscan2
- ARL6IP4 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs1317772776, COSV99758070; called by muse, mutect2, varscan2
- ARMC7 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 54/80 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as COSV55460498; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV63437920; called by muse, mutect2, varscan2
- ARNT2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as COSV57585290; called by muse, mutect2, varscan2
- ARNT2 | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.039); catalogued as COSV57585304; called by muse, mutect2, varscan2
- AS3MT | c.448G>C p.D150H | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54916917; called by muse, mutect2, varscan2
- ASH1L | c.7705G>C p.E2569Q (on ENST00000368346 / NM_001366177.2; = p.E2564Q on NM_018489.3) | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.702); catalogued as COSV64205696; called by muse, mutect2, varscan2
- ASXL2 | c.2204G>A p.G735E | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55458788; called by muse, varscan2
- ASXL2 | c.2132G>C p.R711T | Missense Mutation (SNP) | VAF 116/202 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV55458805, COSV99711222; called by muse, varscan2
- ATAD2 | c.2284G>A p.G762R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as COSV54880892, COSV54883252; called by muse, mutect2, varscan2
- ATE1 | c.565C>A p.H189N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV56436430; called by muse, varscan2
- ATE1 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 20/94 reads (21%) | catalogued as COSV99816647; called by muse, varscan2
- ATP11B | c.3416G>A p.R1139Q | Missense Mutation (SNP) | VAF 84/306 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs768947180, COSV60028684; called by muse, mutect2, varscan2
- ATP1B4 | c.818G>C p.R273T (on ENST00000218008 / NM_001142447.3; = p.R269T on NM_012069.5) | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as COSV54312794; called by muse, mutect2, varscan2
- ATP6V1A | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV56362247; called by muse, mutect2, varscan2
- ATRX | c.3625G>T p.E1209* | Nonsense Mutation (SNP) | VAF 31/143 reads (22%) | catalogued as COSV100969814; called by muse, mutect2, varscan2
- AXDND1 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV62642647, COSV62651391; called by muse, mutect2, varscan2
- AXL | c.1981G>A p.E661K (on ENST00000301178 / NM_021913.5; = p.E652K on NM_001699.6) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV56568269; called by muse, mutect2, varscan2
- BAAT | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52289032; called by muse, mutect2, varscan2
- BAZ2B | c.4928C>G p.S1643C | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV58600878; called by muse, mutect2, varscan2
- BCAS1 | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65085991; called by muse, mutect2, varscan2
- BICC1 | c.2638G>C p.E880Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54063741; called by muse, mutect2, varscan2
- BICRAL | c.3208G>C p.E1070Q | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58405598; called by muse, mutect2, varscan2
- BLM | c.3630G>C p.Q1210H | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV61924127; called by muse, mutect2, varscan2
- BNC2 | c.2881G>A p.D961N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66165524; called by muse, mutect2, varscan2
- BOC | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56350770, COSV56357883; called by muse, mutect2, varscan2
- BPTF | c.4315G>C p.E1439Q | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV58837261; called by muse, mutect2, varscan2
- BRIX1 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV59131325; called by muse, mutect2, varscan2
- BTBD7 | c.3221C>T p.S1074L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV58286000; called by muse, mutect2, varscan2
- BTBD8 | c.748C>G p.Q250E | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV61546305; called by muse, mutect2, varscan2
- BTN3A2 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1489918540, COSV62687258; called by muse, mutect2, varscan2
- BUD13 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as COSV99036337, COSV99496168; called by muse, mutect2, varscan2
- C12orf66 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV61323213; called by muse, mutect2, varscan2
- C1orf94 | c.930G>C p.Q310H (on ENST00000488417 / NM_001134734.2; = p.Q120H on NM_032884.5) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs776385463, COSV64913998; called by muse, mutect2, varscan2
- C5orf22 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); catalogued as COSV57598446; called by muse, mutect2, varscan2
- CA9 | c.956C>G p.S319C | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV61406044, COSV61406606; called by muse, mutect2, varscan2
- CACNA1B | c.3469C>T p.L1157F | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149261457, COSV53126042; called by muse, mutect2, varscan2
- CACNA2D4 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs575121425, COSV54949044; called by muse, mutect2, varscan2
- CACNG7 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs781304642, COSV55813071, COSV55814472; called by muse, varscan2
- CACTIN | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.207); catalogued as rs1294910792, COSV50268164; called by muse, mutect2, varscan2
- CADM2 | c.1222G>A p.E408K (on ENST00000407528 / NM_001167674.2; = p.E410K on NM_153184.4) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV67374720; called by muse, mutect2, varscan2
- CAMSAP2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV52670732; called by muse, mutect2
- CARD18 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 32/125 reads (26%) | catalogued as COSV73233160; called by muse, mutect2, varscan2
- CASK | c.1440G>T p.M480I | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV59366728, COSV59375042; called by muse, mutect2, varscan2
- CCDC121 | c.503G>C p.R168T | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.099); catalogued as COSV53114026, COSV53114740; called by muse, mutect2, varscan2
- CCDC136 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52799574; called by muse, mutect2, varscan2
- CCDC141 | c.2329G>C p.E777Q | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV55373536; called by muse, mutect2, varscan2
- CCDC146 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV53548445; called by muse, varscan2
- CCDC39 | c.1172T>C p.V391A | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.652); catalogued as rs745514628, COSV56484157; called by muse, mutect2, varscan2
- CCDC81 | c.675G>C p.E225D (on ENST00000445632 / NM_001156474.2; = p.E135D on NM_021827.4) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.461); catalogued as COSV53578339; called by muse, mutect2, varscan2
- CCNA2 | c.897G>C p.L299F | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757306594, COSV52655204, COSV52656567; called by muse, mutect2, varscan2
- CCNDBP1 | c.701C>G p.S234* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100281452; called by muse, mutect2, varscan2
- CCNG1 | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.163); catalogued as COSV61652045; called by muse, varscan2
- CD101 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as COSV56718049; called by muse, mutect2, varscan2
- CD163L1 | c.4228G>A p.E1410K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV58016126, COSV58022652; called by muse, mutect2, varscan2
- CD163L1 | c.3706G>C p.E1236Q | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV58016135; called by muse, mutect2, varscan2
- CD300C | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.821); catalogued as COSV58170409; called by muse, mutect2, varscan2
- CDC42BPG | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1396542698, COSV61347385; called by muse, mutect2, varscan2
- CDH24 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99943297; called by muse, mutect2
- CDH7 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as rs757133875, COSV59882171; called by muse, mutect2, varscan2
- CDK11B | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs769701760, COSV58338448; called by muse, mutect2, varscan2
- CDK15 | c.682C>T p.Q228* (on ENST00000652192 / NM_001366386.2; = p.Q177* on NM_139158.2) | Nonsense Mutation (SNP) | VAF 32/80 reads (40%) | catalogued as COSV99642527; called by muse, varscan2
- CDK7 | c.170G>C p.R57T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as COSV56513450; called by muse, mutect2, varscan2
- CDKN1A | c.119del p.G40Afs*108 | Frame Shift Del (DEL) | VAF 35/59 reads (59%) | catalogued as COSV55187136; called by mutect2, pindel, varscan2
- CEACAM21 | c.525C>G p.F175L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1555792566, COSV51814115; called by muse, mutect2, varscan2
- CEBPZ | c.513G>C p.E171D | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.2); catalogued as COSV50017514; called by muse, mutect2, varscan2
- CEP152 | c.3224C>T p.S1075L | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.918); catalogued as rs747274010, COSV57859429; called by muse, mutect2, varscan2
- CEP192 | c.6334C>G p.L2112V | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as COSV58064237; called by muse, mutect2, varscan2
- CEP350 | c.8494G>A p.D2832N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62602489; called by muse, mutect2, varscan2
- CFAP47 | c.4369C>T p.Q1457* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100544772; called by muse, mutect2, varscan2
- CFAP54 | c.6734C>G p.S2245* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as COSV100732850; called by muse, mutect2, varscan2
- CHAF1B | c.1637G>C p.R546T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as COSV58440105; called by muse, mutect2, varscan2
- CIT | c.2713C>T p.R905C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as rs747447396, COSV55868757; called by muse, mutect2, varscan2
- CLCN5 | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56584003; called by muse, mutect2, varscan2
- CLDN4 | c.267C>G p.I89M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as COSV52895542, COSV52895839; called by muse, mutect2, varscan2
- CLIP1 | c.60del p.S20Rfs*4 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | catalogued as COSV56801758; called by mutect2, pindel, varscan2
- CLVS2 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as COSV51562692; called by muse, mutect2, varscan2
- CMYA5 | c.2249C>G p.S750C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV71405915; called by muse, mutect2, varscan2
- CNST | c.1657G>C p.E553Q | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV63621797; called by muse, mutect2, varscan2
- CNTLN | c.2067G>C p.Q689H | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV52078821; called by muse, mutect2, varscan2
- CNTN5 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV54310673; called by muse, mutect2, varscan2
- CNTN5 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV54310706; called by muse, mutect2, varscan2
- CNTN5 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs1448625131, COSV54310717; called by muse, mutect2, varscan2
- CNTNAP2 | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 37/87 reads (43%) | catalogued as COSV62189260; called by muse, mutect2, varscan2
- CNTRL | c.559T>C p.W187R | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV53047027; called by muse, mutect2, varscan2
- COL19A1 | c.2038-1G>A p.X680_splice | Splice Site (SNP) | VAF 21/53 reads (40%) | catalogued as COSV59573369; called by muse, mutect2, varscan2
- COL6A6 | c.5328G>A p.M1776I | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV62022685; called by mutect2, varscan2
- COL7A1 | c.4874G>A p.G1625E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60395269; called by muse, mutect2, varscan2
- COMMD2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1214823753, COSV71946347; called by muse, mutect2, varscan2
- COQ10A | c.743G>C p.*248Sext*69 | Nonstop Mutation (SNP) | VAF 32/76 reads (42%) | catalogued as COSV100369877; called by muse, varscan2
- CPA2 | c.1185G>T p.Q395H | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55979621; called by muse, mutect2, varscan2
- CPNE3 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1430297046, COSV52206408; called by muse, mutect2, varscan2
- CPQ | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV55145908, COSV99610624; called by muse, mutect2, varscan2
- CPT1C | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV99773154, COSV99773175; called by muse, mutect2
- CRB1 | c.3130C>T p.P1044S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66330359; called by muse, mutect2, varscan2
- CRHR1 | c.931-1G>A p.X311_splice (on ENST00000398285 / NM_001145146.2; = p.X282_splice on NM_004382.5) | Splice Site (SNP) | VAF 17/64 reads (27%) | catalogued as COSV53278811; called by muse, mutect2, varscan2
- CRISPLD1 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.292); catalogued as COSV51547938; called by muse, mutect2
- CRK | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.164); catalogued as rs947045345, COSV56030569; called by muse, mutect2, varscan2
- CRX | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.432); catalogued as COSV55758254; called by muse, mutect2, varscan2
- CRYZ | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as COSV61717785; called by muse, mutect2, varscan2
- CSMD1 | c.6826G>A p.D2276N (on ENST00000520002; = p.D2275N on NM_033225.6) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV59324103; called by muse, mutect2, varscan2
- CSRP2 | c.425A>G p.N142S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100222609; called by muse, mutect2
- CTDSP1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV51917088; called by muse, mutect2, varscan2
- CUL3 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as COSV52364829; called by muse, mutect2, varscan2
- CYP2A6 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as COSV56535242; called by muse, mutect2, varscan2
- DALRD3 | c.757G>A p.E253K (on ENST00000341949 / NM_001009996.3; = p.E86K on NM_018114.5) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV58245009, COSV58247569; called by muse, mutect2, varscan2
- DCAF12 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV63511636, COSV63513121; called by muse, mutect2, varscan2
- DCAF4L2 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 17/97 reads (18%) | catalogued as COSV100150373, COSV60477494; called by muse, mutect2, varscan2
- DCHS1 | c.9731C>T p.S3244F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769785819, COSV54997783; called by muse, mutect2, varscan2
- DCHS1 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs751710352, COSV55035621; called by muse, varscan2
- DDX19A | c.765G>C p.Q255H | Missense Mutation (SNP) | VAF 130/183 reads (71%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs767278230, COSV56359868; called by muse, mutect2, varscan2
- DDX31 | c.1265C>T p.S422L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV60134792; called by muse, mutect2, varscan2
- DDX54 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as rs750672319, COSV58373551; called by muse, varscan2
- DENND4A | c.156C>G p.I52M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.774); catalogued as COSV71265800; called by muse, mutect2, varscan2
- DGKK | c.1276C>G p.Q426E | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV65707477, COSV65709477; called by muse, mutect2, varscan2
- DHRS4 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV100365694; called by muse, mutect2, varscan2
- DICER1 | c.1961G>A p.R654K | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58619925; called by muse, mutect2, varscan2
- DISP1 | c.3139G>A p.G1047S | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748488978, COSV52658915; called by muse, mutect2, varscan2
- DISP3 | c.2910C>A p.F970L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.005); catalogued as COSV53827180; called by muse, mutect2, varscan2
- DLC1 | c.3433G>C p.D1145H (on ENST00000276297 / NM_001348081.2; = p.D708H on NM_006094.5) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52304288; called by muse, mutect2, varscan2
- DLX3 | c.61A>T p.S21C | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV71547634; called by muse, mutect2, varscan2
- DMBT1 | c.6827C>T p.S2276F (on ENST00000338354 / NM_001377530.1; = p.S1519F on NM_004406.3) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV57543835; called by muse, mutect2, varscan2
- DMWD | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52176723; called by muse, mutect2, varscan2
- DNAH1 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as rs199910432; called by muse, mutect2, varscan2
- DNAH5 | c.13045G>A p.D4349N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV54224813, COSV54256382; called by muse, mutect2, varscan2
- DNAH8 | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1400940083, COSV59445112, COSV59455903; called by muse, mutect2, varscan2
- DNAJC2 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.652); catalogued as COSV50790479; called by muse, mutect2, varscan2
- DNAJC9 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV99654397; called by muse, mutect2, varscan2
- DOK1 | c.1036C>A p.Q346K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as rs1251247795, COSV51207590; called by muse, mutect2, varscan2
- DPY19L2 | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60543413; called by muse, mutect2, varscan2
- DPYD | c.882C>A p.F294L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV64597728; called by muse, mutect2, varscan2
- DPYS | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 37/174 reads (21%) | catalogued as COSV100679125; called by muse, mutect2, varscan2
- DRAM1 | c.673-1G>C p.X225_splice | Splice Site (SNP) | VAF 28/72 reads (39%) | catalogued as COSV51597845; called by muse, varscan2
- DRGX | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as COSV100938281; called by muse, mutect2, varscan2
- DSPP | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV56810415; called by muse, mutect2, varscan2
- DTNA | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV99310325; called by muse, mutect2
- DUSP8 | c.750C>G p.I250M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59030157; called by muse, mutect2, varscan2
- DYNC2I2 | c.1444G>T p.E482* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | catalogued as COSV100823143; called by muse, mutect2, varscan2
- ECH1 | c.332G>C p.G111A | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55489232; called by muse, mutect2, varscan2
- ECH1 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV55489236; called by muse, mutect2, varscan2
- ECHS1 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63906851; called by muse, mutect2, varscan2
- EFHB | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 75/306 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV55548114; called by muse, mutect2, varscan2
- EIF4E3 | c.378G>A p.W126* (on ENST00000425534 / NM_001134651.2; = p.W20* on NM_173359.5) | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99816120; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 60/89 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as COSV57515814; called by muse, mutect2, varscan2
- ELF3 | c.281G>C p.R94P | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.737); catalogued as COSV62838337, COSV62839839; called by muse, mutect2, varscan2
- ELF3 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV62838350, COSV62839393; called by muse, mutect2, varscan2
- ELFN2 | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV68744136, COSV68744581; called by muse, mutect2, varscan2
- ELP4 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV63352607; called by muse, mutect2, varscan2
- ELP4 | c.516G>C p.Q172H (on ENST00000350638; = p.X172_splice on NM_019040.5) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as COSV63352613; called by muse, mutect2, varscan2
- EMD | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 50/318 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV63962179; called by muse, mutect2, varscan2
- EMILIN2 | c.2781C>G p.N927K | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54423627; called by muse, mutect2, varscan2
- ENTPD1 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV64600588; called by muse, varscan2
- ENTPD1 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100967339; called by muse, varscan2
- EPHX3 | c.465C>G p.I155M | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV55655501; called by muse, mutect2, varscan2
- EPRS1 | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65098894; called by muse, mutect2, varscan2
- ERCC3 | c.1073G>T p.R358I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV53427083; called by muse, mutect2, varscan2
- ETHE1 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV52677634; called by muse, mutect2, varscan2
- EXO1 | c.1084C>G p.Q362E | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV62217550, COSV62220019; called by muse, mutect2, varscan2
- F8 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 146/333 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV64273439; called by muse, mutect2, varscan2
- FAM111B | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs766407917, COSV59111914; called by muse, mutect2, varscan2
- FAM111B | c.1561G>C p.E521Q | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV59111926; called by muse, mutect2, varscan2
- FAM111B | c.1797G>C p.L599F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV100639250, COSV59111936; called by muse, mutect2, varscan2
- FAM187B | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1237062938, COSV61201255; called by mutect2, varscan2
- FAM241B | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV100958439, COSV64768279; called by muse, mutect2
- FAT2 | c.8398G>C p.D2800H | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV55819732; called by muse, mutect2, varscan2
- FAT3 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as COSV53110138, COSV53112772; called by muse, mutect2, varscan2
- FAT4 | c.14363G>T p.G4788V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1288915450, COSV58685383, COSV58708228; called by muse, mutect2, varscan2
- FBLIM1 | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV60029755; called by muse, mutect2, varscan2
- FBLN2 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.578); catalogued as rs199855306, COSV55483030, COSV55484517; called by muse, mutect2, varscan2
- FBLN7 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs766836093, COSV55616046; called by muse, mutect2, varscan2
- FBXL5 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs1317628203, COSV58011012; called by muse, mutect2, varscan2
- FBXO42 | c.282G>A p.M94I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV65045694; called by muse, mutect2, varscan2
- FBXW10 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV57317124; called by muse, mutect2, varscan2
- FEZ1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs867006645, COSV54028631; called by muse, mutect2, varscan2
- FGF10 | c.32C>G p.S11* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV52939708, COSV99239952; called by muse, mutect2, varscan2
- FKBP15 | c.1186C>G p.L396V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.26); catalogued as COSV53034785; called by muse, mutect2, varscan2
- FMO5 | c.1266G>C p.E422D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs961562235, COSV54206679, COSV99567499; called by muse, mutect2, varscan2
- FRAS1 | c.3973C>T p.Q1325* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99347132; called by muse, mutect2, varscan2
- FSIP2 | c.19525G>C p.D6509H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.561); catalogued as COSV58085766; called by muse, mutect2, varscan2
- FTSJ3 | c.2045G>C p.R682T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63789453, COSV63790123; called by muse, mutect2, varscan2
- GABRB1 | c.991T>C p.F331L | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV54981751; called by muse, mutect2, varscan2
- GALNTL6 | c.192G>C p.L64F | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.467); catalogued as COSV72488723, COSV72490836; called by muse, mutect2, varscan2
- GANAB | c.2469G>A p.M823I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV55488721, COSV55489135; called by muse, mutect2, varscan2
- GBP5 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 41/163 reads (25%) | catalogued as COSV58593682; called by muse, mutect2, varscan2
- GBP6 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100969431; called by muse, mutect2, varscan2
- GDI2 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV60167484; called by muse, mutect2, varscan2
- GEN1 | c.1152G>A p.M384I | Missense Mutation (SNP) | VAF 68/129 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV58056594; called by muse, mutect2, varscan2
- GIMAP6 | c.105G>C p.Q35H | Missense Mutation (SNP) | VAF 58/270 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV61033405; called by muse, mutect2, varscan2
- GIP | c.348G>T p.Q116H | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.436); catalogued as COSV62467228; called by muse, mutect2, varscan2
- GLB1L2 | c.1556G>A p.R519K | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761945171, COSV56997010; called by muse, mutect2, varscan2
- GLMN | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as COSV64860424; called by muse, mutect2, varscan2
- GNB3 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.744); catalogued as COSV51833124; called by muse, mutect2, varscan2
- GNB4 | c.109A>G p.M37V | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1394200676, COSV51709581; called by muse, mutect2, varscan2
- GNPTAB | c.3092G>A p.R1031Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs758294588, COSV54776970; called by muse, mutect2, varscan2
- GNRHR | c.924C>G p.F308L | Missense Mutation (SNP) | VAF 68/129 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV56933576; called by muse, mutect2, varscan2
- GOLGB1 | c.7512G>C p.E2504D | Missense Mutation (SNP) | VAF 116/235 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61461855, COSV61465836; called by muse, mutect2, varscan2
- GOLGB1 | c.7394C>G p.S2465C | Missense Mutation (SNP) | VAF 81/194 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61465840; called by muse, varscan2
- GOLM2 | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as COSV55463310; called by muse, mutect2, varscan2
- GOLPH3 | c.730C>G p.H244D | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV54060792; called by muse, mutect2, varscan2
- GPAT2 | c.1645G>A p.V549I | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs775199489, COSV64003419; called by muse, mutect2, varscan2
- GPATCH8 | c.648C>G p.F216L | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.985); catalogued as rs775156946, COSV59194922; called by muse, mutect2, varscan2
- GPR141 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57731278, COSV57732248; called by muse, mutect2, varscan2
- GPR153 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV64938524; called by muse, mutect2, varscan2
- GRB10 | c.1394G>A p.R465Q (on ENST00000398812; = p.R419Q on NM_001001549.3) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs924140952, COSV60010598; called by muse, mutect2, varscan2
- GRTP1 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.372); catalogued as COSV64902370; called by muse, mutect2, varscan2
- GSAP | c.696C>G p.I232M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs756308900, COSV57529978; called by muse, mutect2, varscan2
- GSTM5 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV56658061; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as COSV56086699; called by muse, mutect2, varscan2
- GTF3C1 | c.486G>C p.L162F | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62241267, COSV62241447; called by muse, mutect2, varscan2
- GYG1 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56049699; called by muse, mutect2
- GZF1 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.261); catalogued as COSV57636107; called by muse, mutect2
- H2AC12 | c.71_74del p.L24Rfs*35 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | catalogued as COSV63617040; called by mutect2, pindel, varscan2
- H2AC15 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57585632, COSV57586672; called by muse, mutect2, varscan2
- H2BU1 | c.374C>G p.S125C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as COSV64209737; called by muse, mutect2
- H4C9 | c.143C>G p.S48C | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62889826; called by muse, mutect2, varscan2
- HACL1 | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV100329380, COSV100329797; called by mutect2, varscan2
- HAUS6 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs151253216; called by muse, mutect2, varscan2
- HCN3 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100751768, COSV62876739; called by muse, mutect2
- HCN4 | c.2974A>G p.S992G | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV99983138; called by muse, mutect2, varscan2
- HEG1 | c.1486G>C p.G496R | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV60762070; called by muse, mutect2, varscan2
- HFM1 | c.3594G>C p.Q1198H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99645079; called by muse, mutect2
- HFM1 | c.3214C>G p.L1072V | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV54027194; called by muse, mutect2, varscan2
- HGD | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52198245; called by muse, mutect2, varscan2
- HGF | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as rs1486090533, COSV55945812, COSV99737561; called by muse, mutect2, varscan2
- HHIP | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as rs1378560908, COSV56836355, COSV56839702, COSV56843149; called by muse, mutect2
- HHIPL2 | c.867C>G p.F289L | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.062); catalogued as rs1187063026, COSV58564669, COSV58565183; called by muse, mutect2, varscan2
- HIPK3 | c.2777C>T p.S926F | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV57562555; called by muse, mutect2, varscan2
- HIRIP3 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV54229919; called by muse, mutect2, varscan2
- HLCS | c.1433C>T p.T478M | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748265752, COSV60793683; called by muse, mutect2, varscan2
- HMGCS1 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1388459941, COSV57290154, COSV57290874; called by muse, mutect2, varscan2
- HNF4G | c.908T>C p.I303T (on ENST00000354370 / NM_001330561.2; = p.I350T on NM_004133.5) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV62968609; called by muse, mutect2, varscan2
- HOXA11 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 112/150 reads (75%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs926107951, COSV50053112; called by muse, mutect2, varscan2
- HS3ST2 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.332); catalogued as COSV99757534; called by muse, mutect2
- HS6ST1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs766302801, COSV52126896; called by muse, mutect2, varscan2
- HSPB3 | c.332C>G p.S111* | Nonsense Mutation (SNP) | VAF 19/68 reads (28%) | catalogued as COSV100115848; called by muse, mutect2, varscan2
- HSPG2 | c.11380G>A p.E3794K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs775485358, COSV65933153; called by muse, mutect2, varscan2
- HTATSF1 | c.1004G>A p.R335K | Missense Mutation (SNP) | VAF 99/272 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54478917; called by muse, mutect2, varscan2
- HTT | c.3239C>A p.P1080Q | Missense Mutation (SNP) | VAF 73/318 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61860461, COSV61862041; called by muse, mutect2, varscan2
- IBTK | c.1102C>G p.Q368E | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV60392906, COSV60396770; called by muse, mutect2, varscan2
- ICAM5 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 11/86 reads (13%) | catalogued as COSV99703019; called by muse, mutect2, varscan2
- IFIH1 | c.2089G>T p.E697* | Nonsense Mutation (SNP) | VAF 28/73 reads (38%) | catalogued as COSV55128388, COSV99718311; called by muse, mutect2, varscan2
- IGF2BP1 | c.408C>G p.I136M | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.196); catalogued as COSV51731334; called by muse, mutect2, varscan2
- IGF2R | c.6068C>T p.S2023L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as rs1196014783, COSV63629166; called by muse, mutect2, varscan2
- IGHA1 | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as rs762698823; called by muse, varscan2
- IGSF22 | c.2114C>G p.S705C (on ENST00000319338; = p.S806C on NM_173588.4) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV60034228; called by muse, mutect2, varscan2
- IKBKG | c.142C>G p.P48A | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.076); catalogued as COSV54838518; called by muse, mutect2, varscan2
- IL18R1 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV52122673; called by muse, mutect2, varscan2
- IL36B | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV52086369, COSV52086934; called by muse, mutect2, varscan2
- IL4R | c.2466G>A p.M822I | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.066); catalogued as rs768558701, COSV50143830; called by muse, varscan2
- IL6 | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV51732744; called by muse, mutect2, varscan2
- INHBA | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99636969; called by muse, varscan2
- INSRR | c.1948G>A p.D650N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.248); catalogued as COSV63873164; called by muse, mutect2, varscan2
- IRF4 | c.718A>G p.R240G | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as COSV66705203; called by muse, mutect2, varscan2
- ITGB1BP1 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53006145; called by muse, mutect2, varscan2
- ITK | c.375G>C p.W125C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70062331; called by muse, mutect2, varscan2
- JAKMIP2 | c.1121T>G p.L374* | Nonsense Mutation (SNP) | VAF 22/38 reads (58%) | catalogued as COSV99507077; called by muse, mutect2, varscan2
- KCNJ3 | c.1251G>C p.L417F | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV54536193, COSV54543247; called by muse, mutect2, varscan2
- KDM5C | c.1950G>C p.K650N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.274); catalogued as COSV64764992, COSV64765770; called by muse, mutect2, varscan2
- KDM6A | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65040195; called by muse, mutect2, varscan2
- KIAA1328 | c.1652C>G p.S551* | Nonsense Mutation (SNP) | VAF 16/24 reads (67%) | catalogued as COSV54448189, COSV99692896; called by muse, mutect2, varscan2
- KIF21A | c.4012del p.Q1338Sfs*5 (on ENST00000361418 / NM_001378440.1; = p.Q1325Sfs*5 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | catalogued as COSV62771545; called by mutect2, pindel, varscan2
- KIF21B | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV100144596, COSV59754367, COSV59769096; called by muse, mutect2, varscan2
- KIFC1 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100997079, COSV65737545; called by muse, mutect2, varscan2
- KLHL40 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV55134585; called by muse, mutect2, varscan2
- KLHL6 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs1269273965, COSV58066392; called by muse, mutect2, varscan2
- KLK5 | c.524C>A p.S175Y | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60450337; called by muse, mutect2, varscan2
- KLRK1 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs773312579, COSV53698539; called by muse, mutect2, varscan2
- KMT2D | c.14659G>C p.E4887Q | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as CM156943, COSV56439572, COSV99976438; called by muse, mutect2, varscan2
- KMT2D | c.12850C>T p.Q4284* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | catalogued as COSV56457449; called by muse, mutect2, varscan2
- KMT2D | c.9370G>A p.E3124K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs778308911, COSV56439591; called by muse, varscan2
- KRTAP15-1 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as rs1266940514, COSV61877398; called by muse, mutect2, varscan2
- KRTCAP3 | c.252G>C p.R84S | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV51994192; called by muse, mutect2, varscan2
- LAMA1 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67536975; called by muse, mutect2, varscan2
- LARP4 | c.79C>G p.P27A | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV53322573; called by muse, mutect2, varscan2
- LCMT2 | c.1819C>T p.H607Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as COSV59790424; called by muse, mutect2, varscan2
- LHX5 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55662812; called by muse, mutect2, varscan2
- LIFR | c.2731C>G p.L911V | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54690145; called by muse, mutect2, varscan2
- LIMK2 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 180/346 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.265); catalogued as COSV53223661, COSV99313900; called by muse, mutect2, varscan2
- LIN54 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs1264841525, COSV61201134; called by muse, mutect2, varscan2
- LMAN2 | c.681G>C p.M227I | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.648); catalogued as COSV57424604; called by muse, mutect2, varscan2
- LMBRD2 | c.1557G>T p.M519I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV56949995; called by muse, mutect2, varscan2
- LRP1 | c.7614C>G p.I2538M | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV54511279; called by muse, mutect2, varscan2
- LRRC3 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as rs1412198700, COSV52399260, COSV99381714; called by muse, mutect2, varscan2
- LRRFIP2 | c.1735G>T p.E579* | Nonsense Mutation (SNP) | VAF 48/125 reads (38%) | catalogued as COSV100368073; called by muse, mutect2, varscan2
- LRRN2 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65783781; called by muse, mutect2, varscan2
- LRSAM1 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs771380760, COSV55940047; called by muse, mutect2, varscan2
- LXN | c.399G>A p.M133I | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV51832695; called by muse, mutect2, varscan2
- MACF1 | c.11888C>T p.S3963L (on ENST00000372915; = p.S1896L on NM_012090.5) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV57121097; called by muse, mutect2, varscan2
- MACF1 | c.18169G>C p.E6057Q (on ENST00000372915; = p.E4102Q on NM_012090.5) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as rs1407537347, COSV57121119; called by muse, mutect2, varscan2
- MAGED2 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99514333; called by muse, mutect2
- MAN1A2 | c.1148G>C p.R383T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV62978496; called by muse, mutect2, varscan2
- MAN2A2 | c.1390C>T p.L464F | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64638292; called by muse, mutect2
- MAN2B2 | c.2326G>C p.E776Q | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as COSV53452999, COSV53453849; called by muse, mutect2, varscan2
- MAP4K3 | c.959G>A p.R320K | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as COSV55713215; called by muse, mutect2, varscan2
- MAPK14 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV100004566; called by muse, mutect2, varscan2
- MAPK6 | c.1460C>G p.S487C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.135); catalogued as COSV55929974; called by muse, mutect2, varscan2
- MAU2 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.722); catalogued as COSV53235389; called by muse, mutect2, varscan2
- MBD5 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV68697007; called by muse, mutect2, varscan2
- MCM5 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1160722114, COSV53346249; called by muse, mutect2, varscan2
- MECP2 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 100/321 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57653864; called by muse, mutect2, varscan2
- MED1 | c.767C>A p.S256* | Nonsense Mutation (SNP) | VAF 24/168 reads (14%) | catalogued as COSV100327251, COSV100328208; called by muse, mutect2, varscan2
- MELTF | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV56381262; called by muse, mutect2, varscan2
- MFSD8 | c.1514G>C p.R505T | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56551181; called by muse, mutect2, varscan2
- MGAM | c.232C>G p.P78A | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV71885453; called by muse, mutect2, varscan2
- MID1 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs747456797, COSV58194532; called by muse, mutect2, varscan2
- MIER1 | c.1393G>C p.E465Q (on ENST00000355356 / NM_001077701.3; = p.E482Q on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.366); catalogued as COSV62530283; called by muse, mutect2, varscan2
- MIER2 | c.972C>G p.I324M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53395776, COSV53397556; called by muse, mutect2, varscan2
- MIOS | c.2267G>C p.R756T | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV60768404; called by muse, mutect2, varscan2
- MKI67 | c.3280G>C p.E1094Q | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.76); catalogued as COSV64074346; called by muse, mutect2, varscan2
- MKI67 | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 54/116 reads (47%) | catalogued as COSV100896018, COSV100896830; called by muse, mutect2, varscan2
- MLNR | c.987G>C p.M329I | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.096); catalogued as COSV54531184, COSV54532714; called by muse, mutect2, varscan2
- MNAT1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as COSV54190580, COSV54190636; called by muse, mutect2, varscan2
- MOCS1 | c.1588G>C p.G530R | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51318129; called by muse, mutect2, varscan2
- MOV10L1 | c.2071-1G>A p.X691_splice | Splice Site (SNP) | VAF 25/41 reads (61%) | catalogued as COSV53169881; called by muse, mutect2, varscan2
- MPHOSPH6 | c.459G>C p.K153N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV50736799, COSV99259374; called by muse, mutect2, varscan2
- MPP5 | c.720G>C p.E240D | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV55529773; called by muse, mutect2, varscan2
- MPP6 | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV56038305; called by muse, mutect2, varscan2
- MPP7 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as COSV61732426; called by muse, mutect2, varscan2
- MRM2 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as rs749671512, COSV54248111; called by muse, mutect2, varscan2
- MRPL37 | c.318C>G p.I106M | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.622); catalogued as COSV55277395; called by muse, mutect2, varscan2
- MRPS18B | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.115); catalogued as rs1413876351, COSV52541548; called by muse, mutect2, varscan2
- MRPS21 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100481616; called by muse, mutect2, varscan2
- MRTFB | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs1317035705, COSV57958164; called by muse, mutect2, varscan2
- MSH2 | c.2191G>C p.E731Q | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD117459, CM064124, COSV104373276, COSV51879313; called by muse, mutect2, varscan2
- MSH6 | c.2476C>A p.H826N | Missense Mutation (SNP) | VAF 55/85 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52279336; called by muse, mutect2, varscan2
- MSLN | c.1838G>C p.G613A (on ENST00000382862 / NM_013404.4; = p.G605A on NM_005823.6) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as COSV53502084; called by muse, mutect2, varscan2
- MTERF3 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV54629861; called by muse, mutect2, varscan2
- MTNR1B | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 56/239 reads (23%) | catalogued as rs373981936, COSV99924882; called by muse, mutect2, varscan2
- MTR | c.1748C>G p.S583C | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV63964909; called by muse, mutect2, varscan2
- MUC16 | c.11132C>G p.S3711C | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV67465890, COSV67479665; called by muse, mutect2
- MUC17 | c.7444G>C p.D2482H | Missense Mutation (SNP) | VAF 124/448 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.603); catalogued as rs1228258168, COSV60288511; called by muse, mutect2, varscan2
- MUC17 | c.8653G>C p.E2885Q | Missense Mutation (SNP) | VAF 94/454 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as COSV100074705, COSV60288520; called by muse, mutect2, varscan2
- MUC17 | c.8830G>C p.E2944Q | Missense Mutation (SNP) | VAF 69/387 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.727); catalogued as COSV60283186; called by muse, mutect2, varscan2
- MUSK | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51886080; called by muse, mutect2, varscan2
- MUSK | c.1210C>G p.L404V | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as COSV51886108; called by muse, mutect2, varscan2
- MVP | c.2452C>T p.Q818* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100651445; called by muse, mutect2
- MX1 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55819234; called by muse, mutect2, varscan2
- MYADM | c.428_430del p.F143del | In Frame Del (DEL) | VAF 16/94 reads (17%) | catalogued as rs1332673811; called by pindel, varscan2
- MYG1 | c.162C>G p.F54L | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV54475941; called by muse, mutect2, varscan2
- MYH11 | c.5265G>C p.M1755I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55552884, COSV55553173; called by muse, mutect2, varscan2
- MYH11 | c.5146G>C p.E1716Q | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as COSV55553192; called by muse, mutect2, varscan2
- MYH14 | c.5906C>T p.S1969F | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99221418; called by muse, mutect2
- MYH2 | c.3093C>G p.I1031M | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV55438292, COSV99819030; called by muse, mutect2, varscan2
- MYH4 | c.508C>A p.R170S | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs201645314, COSV55118188; called by muse, mutect2, varscan2
- MYO10 | c.3086C>G p.S1029C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.747); catalogued as COSV57021642; called by muse, mutect2, varscan2
- MYO9A | c.7138G>A p.E2380K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61851081; called by muse, mutect2, varscan2
- MYO9B | c.5956G>A p.E1986K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV55727791; called by muse, mutect2, varscan2
- MYPN | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV100589401; called by muse, mutect2, varscan2
- MYSM1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1341551181, COSV71763166; called by muse, mutect2, varscan2
- NARS2 | c.1128C>G p.F376L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55251741; called by muse, varscan2
- NBPF1 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.859); catalogued as rs761369854, COSV101236055, COSV101236686; called by muse, mutect2
- NCEH1 | c.661G>A p.D221N (on ENST00000538775; = p.D181N on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV56434622; called by muse, mutect2, varscan2
- NCKAP5L | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV60129603; called by muse, mutect2, varscan2
- NCOA1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV56044137; called by muse, mutect2, varscan2
- NDUFV2 | c.81G>C p.K27N | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as COSV59187247; called by muse, mutect2, varscan2
- NEK11 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.039); catalogued as rs752333655, COSV63580933; called by mutect2, varscan2
- NFS1 | c.1062C>G p.I354M | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV65053834; called by muse, mutect2, varscan2
- NID1 | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as COSV51620278; called by muse, mutect2, varscan2
- NKX2-5 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.68); PolyPhen benign (0.013); catalogued as COSV61299044; called by muse, mutect2, varscan2
- NLRC4 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61592628; called by muse, mutect2, varscan2
- NLRC4 | c.2026G>C p.D676H | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100707506, COSV61592633; called by muse, mutect2, varscan2
- NLRC4 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as COSV61592662, COSV99048594; called by muse, mutect2, varscan2
- NLRC4 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV61592469, COSV61592671, COSV61594910; called by muse, varscan2
- NLRC4 | c.1044G>C p.Q348H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV61592676; called by muse, mutect2, varscan2
- NLRC4 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61592681; called by muse, mutect2, varscan2
- NLRC4 | c.768G>C p.Q256H | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100707331, COSV61592687; called by muse, varscan2
- NOP14 | c.1581G>C p.E527D | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV58625262; called by muse, mutect2, varscan2
- NOTCH3 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.617); catalogued as rs1386908989, CM0911494, COSV54634806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPEPPS | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 82/127 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV59102508; called by muse, mutect2, varscan2
- NRBP1 | c.956G>C p.R319T | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV51994188; called by muse, mutect2, varscan2
- NRDC | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV61404335; called by muse, mutect2, varscan2
- NRDC | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1007683384, COSV61404350; called by muse, mutect2, varscan2
- NRXN1 | c.2665G>A p.D889N | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV100452616; called by muse, mutect2
- NRXN1 | c.1896G>C p.W632C | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58452784; called by muse, mutect2
- NSD1 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV61776327; called by muse, mutect2, varscan2
- NSMCE4A | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV64632805; called by muse, mutect2, varscan2
- NUP107 | c.2578C>G p.L860V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs755619071, COSV57494796; called by muse, varscan2
- NUP210L | c.5548C>G p.L1850V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV55147267; called by muse, mutect2, varscan2
- NUP35 | c.192G>A p.M64I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54557920; called by muse, mutect2, varscan2
- NVL | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55872560; called by muse, mutect2, varscan2
- NXF1 | c.62G>C p.R21T | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.738); catalogued as COSV53674094; called by muse, mutect2, varscan2
- OPTN | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as COSV53810781, COSV53811737, COSV53813177; called by muse, mutect2, varscan2
- OR1L8 | c.169C>G p.Q57E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV59186392; called by muse, mutect2, varscan2
- OR2H1 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as COSV65810678; called by muse, mutect2, varscan2
- OR2T33 | c.861C>G p.I287M | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58815386; called by muse, mutect2, varscan2
- OR4D9 | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs774458511, COSV61434708; called by muse, mutect2, varscan2
- OR52E2 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV58612313; called by muse, mutect2
- OR52K2 | c.777C>G p.I259M | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs770582037, COSV57834593, COSV57835081; called by muse, mutect2, varscan2
- OR6M1 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.052); catalogued as COSV58433577; called by muse, mutect2, varscan2
- PAFAH2 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV65339497; called by muse, mutect2, varscan2
- PARS2 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64883553; called by muse, mutect2, varscan2
- PATZ1 | c.2032G>C p.D678H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV56743711; called by muse, varscan2
- PATZ1 | c.985C>G p.P329A | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0.101); catalogued as COSV53229365; called by muse, mutect2, varscan2
- PC | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV63080594; called by muse, varscan2
- PC | c.324G>C p.E108D | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV63080609; called by muse, varscan2
- PCDHA8 | c.1033G>C p.D345H | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100970310, COSV100970528; called by muse, mutect2, varscan2
- PCNX2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as rs775590596, COSV50784127; called by muse, mutect2, varscan2
- PCSK1 | c.1669C>T p.H557Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60735254; called by muse, mutect2, varscan2
- PCSK1 | c.260C>G p.T87S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.729); catalogued as COSV60735263; called by muse, mutect2, varscan2
- PDE4DIP | c.1561G>C p.E521Q | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57695959; called by muse, mutect2, varscan2
- PDGFD | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as COSV56378234, COSV56380886; called by muse, mutect2, varscan2
- PDHA2 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV54779225; called by muse, mutect2, varscan2
- PDLIM1 | c.389C>G p.S130W | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100267665, COSV61473990; called by muse, mutect2, varscan2
- PDX1 | c.555G>C p.L185F | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66847090; called by muse, mutect2, varscan2
- PGGHG | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV67140823; called by muse, mutect2, varscan2
- PGM3 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.053); catalogued as rs748552273, COSV52283883; called by mutect2, varscan2
- PGM5 | c.1366G>C p.D456H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV67167116, COSV67167683; called by muse, mutect2, varscan2
- PHF19 | c.759C>G p.I253M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as rs759656370, COSV56489732, COSV56490766; called by muse, mutect2, varscan2
- PHKA1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59805806; called by muse, mutect2, varscan2
- PHKA2 | c.3571G>C p.D1191H | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV66053957; called by muse, mutect2, varscan2
- PIAS1 | c.1308G>C p.L436F | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV51031999; called by muse, mutect2, varscan2
- PIGQ | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV50313735; called by muse, mutect2, varscan2
- PIP5K1C | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1235834771, COSV58952392; called by muse, mutect2, varscan2
- PKHD1 | c.10844G>A p.R3615K | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs776969998, COSV64390154; called by muse, mutect2, varscan2
- PLD6 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); catalogued as COSV58634025; called by muse, mutect2, varscan2
- PLEC | c.7336G>A p.E2446K (on ENST00000322810 / NM_201380.4; = p.E2336K on NM_000445.5) | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as COSV59635978, COSV59654826; called by muse, varscan2
- PLEC | c.6187G>A p.E2063K (on ENST00000322810 / NM_201380.4; = p.E1953K on NM_000445.5) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs782016873, COSV59636062; called by muse, mutect2, varscan2
- PLEKHA5 | c.2183A>G p.D728G | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV54700728; called by muse, mutect2, varscan2
- PLEKHA7 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV100850414, COSV63046168; called by muse, mutect2, varscan2
- PLEKHG4 | c.2038C>T p.R680W | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs1306810002, COSV58572900; called by muse, mutect2, varscan2
- PLEKHG4 | c.3287C>G p.S1096W | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV58572905; called by muse, mutect2
- PLK3 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.061); catalogued as rs17880829, COSV100221322; called by muse, mutect2, varscan2
- PLXNA1 | c.4670-1G>A p.X1557_splice | Splice Site (SNP) | VAF 13/62 reads (21%) | catalogued as COSV52526126, COSV52532990; called by muse, mutect2, varscan2
- PLXNB2 | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs756708347, COSV63781710; called by muse, mutect2, varscan2
- PLXNC1 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.13); catalogued as COSV51575322; called by muse, mutect2, varscan2
- PNLDC1 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV51705508; called by muse, mutect2, varscan2
- POC1A | c.1138C>G p.L380V | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56591450; called by muse, mutect2, varscan2
- POGLUT1 | c.59C>G p.S20* | Nonsense Mutation (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99809349; called by muse, mutect2
- POP1 | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs774195595, COSV62892764; called by muse, mutect2, varscan2
- POT1 | c.749C>G p.S250* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100713947, COSV62934014; called by muse, mutect2, varscan2
- PPARGC1A | c.2052C>G p.I684M | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV53524382, COSV53527611; called by muse, mutect2, varscan2
- PPFIBP1 | c.988C>T p.R330* (on ENST00000318304 / NM_177444.3; = p.R310* on NM_003622.4) | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as rs1470555299, COSV99944136; called by muse, mutect2, varscan2
- PPM1L | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV72263193; called by muse, mutect2, varscan2
- PRAM1 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs780939914, COSV55313736; called by muse, mutect2, varscan2
- PRCC | c.735C>G p.I245M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs778366157, COSV54856258; called by muse, mutect2, varscan2
- PRPF31 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs753445887, COSV58085324; called by muse, mutect2, varscan2
- PRR14 | c.1525del p.L509* | Frame Shift Del (DEL) | VAF 21/86 reads (24%) | catalogued as COSV54911765; called by mutect2, pindel, varscan2
- PRR23B | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV61493438; called by muse, mutect2, varscan2
- PSD | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV50045898; called by muse, mutect2, varscan2
- PSD4 | c.2311C>G p.Q771E | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV55526760; called by muse, mutect2, varscan2
- PSIP1 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1233260750, COSV101050868, COSV66254538; called by muse, mutect2, varscan2
- PSMA1 | c.562G>C p.V188L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV67165937; called by muse, mutect2, varscan2
- PSMC4 | c.210G>C p.K70N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV50095203, COSV99338260; called by muse, mutect2, varscan2
- PTGER1 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs200887614, COSV52875119; called by muse, mutect2, varscan2
- PTGER2 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.41); catalogued as COSV55418806; called by muse, mutect2, varscan2
- PTPN13 | c.7138G>C p.D2380H (on ENST00000411767 / NM_080683.3; = p.D2361H on NM_006264.3) | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57407705; called by muse, mutect2, varscan2
- PTPN5 | c.1597C>T p.Q533* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100078948; called by muse, mutect2, varscan2
- PTPRD | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV61945917; called by muse, mutect2, varscan2
- PTPRF | c.4187C>G p.S1396C | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV63444966; called by muse, mutect2, varscan2
- PTPRR | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.399); catalogued as rs753337673, COSV51732233; called by muse, mutect2, varscan2
- PXN | c.1770C>G p.F590L (on ENST00000228307 / NM_001080855.3; = p.F556L on NM_002859.4) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57218802; called by muse, mutect2, varscan2
- R3HCC1L | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100106985; called by muse, mutect2, varscan2
- RAB11FIP5 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769351049, COSV50249427; called by muse, mutect2, varscan2
- RAB25 | c.476C>G p.S159C | Missense Mutation (SNP) | VAF 168/421 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV63108055; called by muse, mutect2, varscan2
- RALY | c.188C>G p.S63C | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); catalogued as COSV55781234; called by muse, mutect2, varscan2
- RANBP6 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as COSV52389407; called by muse, mutect2, varscan2
- RAP2A | c.117C>A p.F39L | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV55355069; called by muse, mutect2, varscan2
- RAPSN | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1452482859, COSV54084475; called by muse, mutect2, varscan2
- RASSF9 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV100771346, COSV63433668; called by muse, mutect2, varscan2
- RB1 | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV57309261; called by muse, mutect2, varscan2
- RBBP6 | c.304-1G>C p.X102_splice | Splice Site (SNP) | VAF 15/75 reads (20%) | catalogued as COSV60505162; called by muse, mutect2, varscan2
- RBBP8 | c.1279G>C p.D427H | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV59092644; called by muse, mutect2, varscan2
- RBM15 | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs763334210, COSV63923518; called by muse, mutect2
- RBM17 | c.804G>C p.E268D | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65913738, COSV65913983; called by muse, mutect2, varscan2
- RBM19 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV55692203; called by muse, mutect2, varscan2
- RGPD2 | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100552796; called by mutect2, varscan2
- RGS22 | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV62661734; called by muse, mutect2, varscan2
- RHOXF2 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 44/165 reads (27%) | catalogued as COSV101002749; called by muse, mutect2, varscan2
- RIMS2 | c.847C>T p.Q283* (on ENST00000666250 / NM_001348490.2; = p.Q91* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV51669664; called by muse, mutect2, varscan2
- RLBP1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.456); catalogued as CM1412060, COSV51528109, COSV99175311; called by muse, mutect2, varscan2
- RMI1 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756364458, COSV57936280; called by muse, mutect2, varscan2
- RORC | c.1305G>T p.E435D | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV59092985; called by muse, mutect2, varscan2
- RPL7 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.292); catalogued as COSV99536035; called by muse, mutect2, varscan2
- RPS15 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV51833514; called by muse, mutect2, varscan2
- RPS2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.08); catalogued as COSV51910042; called by muse, mutect2, varscan2
- RRP12 | c.2543C>T p.S848L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs754064680, COSV59667530; called by muse, mutect2, varscan2
- RYR3 | c.11869G>A p.E3957K (on ENST00000389232; = p.E3958K on NM_001036.6) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759404174, COSV66789369; called by muse, mutect2, varscan2
- SALL1 | c.319C>G p.Q107E | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV51757400; called by muse, mutect2, varscan2
- SBNO1 | c.673G>C p.D225H (on ENST00000420886; = p.D224H on NM_018183.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV57341678; called by muse, mutect2, varscan2
- SCAMP3 | c.110C>G p.T37R | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); catalogued as COSV56945083; called by muse, mutect2, varscan2
- SCML2 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 14/96 reads (15%) | catalogued as COSV99318431; called by muse, varscan2
- SCML2 | c.146C>A p.S49* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | catalogued as COSV99318433; called by muse, varscan2
- SCN5A | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs1364304621, COSV61124121, COSV61140978; called by muse, mutect2, varscan2
- SCN9A | c.2967G>C p.Q989H (on ENST00000303354; = p.Q978H on NM_002977.3) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV57609954; called by muse, mutect2, varscan2
- SCNN1A | c.1460C>G p.S487C | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57434319, COSV57435517; called by muse, mutect2, varscan2
- SEC24D | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54879821; called by muse, mutect2, varscan2
- SECISBP2L | c.1258G>A p.D420N (on ENST00000559471 / NM_001193489.2; = p.D375N on NM_014701.4) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV55934445; called by muse, mutect2, varscan2
- SEMA4G | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52968142; called by muse, varscan2
- SEMA4G | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV52968174; called by muse, varscan2
- SERPINB2 | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV55091920; called by muse, mutect2, varscan2
- SESN3 | c.108G>C p.L36F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as rs748459759, COSV53584956; called by muse, mutect2, varscan2
- SETD3 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777564821, COSV59284449; called by muse, mutect2, varscan2
- SF3B3 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 10/219 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV56786266, COSV56787590; called by muse, mutect2
- SFSWAP | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV55521986; called by muse, mutect2
- SH3D21 | c.1980C>G p.I660M (on ENST00000453908 / NM_001162530.2; = p.I549M on NM_024676.5) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs1466407650, COSV54634205; called by muse, mutect2, varscan2
- SHBG | c.875C>A p.S292* | Nonsense Mutation (SNP) | VAF 52/73 reads (71%) | catalogued as COSV99352060; called by muse, mutect2, varscan2
- SHE | c.457C>G p.Q153E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV59071799; called by muse, mutect2, varscan2
- SHH | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs141313715; called by muse, mutect2, varscan2
- SHROOM3 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as rs140762344, COSV56031590; called by muse, mutect2, varscan2
- SIGLEC1 | c.3236C>T p.S1079L | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV52459792; called by muse, mutect2, varscan2
- SIPA1L2 | c.1292C>G p.S431* | Nonsense Mutation (SNP) | VAF 53/166 reads (32%) | catalogued as COSV53395367, COSV99476893; called by muse, mutect2, varscan2
- SKP1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV60435666, COSV60436065; called by muse, mutect2, varscan2
- SLC12A7 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53757276, COSV99369889; called by muse, mutect2, varscan2
- SLC13A3 | c.1607C>T p.S536F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.963); catalogued as COSV51719105, COSV99285929; called by muse, mutect2
- SLC19A1 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60754569, COSV60755283; called by muse, mutect2, varscan2
- SLC22A11 | c.886C>G p.L296V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57253155; called by muse, mutect2, varscan2
- SLC22A8 | c.776C>A p.S259Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60324969, COSV60324984; called by muse, mutect2, varscan2
- SLC24A5 | c.1394G>A p.R465K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV51047622; called by muse, mutect2, varscan2
- SLC29A4 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51874173; called by muse, mutect2, varscan2
- SLC2A1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV65287442; called by muse, mutect2, varscan2
- SLC2A6 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.125); catalogued as rs782755979, COSV52469969; called by muse, mutect2, varscan2
- SLC34A1 | c.1290C>T p.I430= | Splice Region (SNP) | VAF 42/64 reads (66%) | catalogued as rs774126797, COSV60995780; called by muse, mutect2, varscan2
- SLC35G6 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59492244; called by muse, mutect2, varscan2
- SLC39A12 | c.1534-1G>A p.X512_splice (on ENST00000377369 / NM_001145195.2; = p.X475_splice on NM_152725.3) | Splice Site (SNP) | VAF 8/50 reads (16%) | catalogued as COSV101069780; called by muse, mutect2
- SLC3A1 | c.1259C>G p.S420C | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1031709288, CM981839, COSV53222608; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC44A2 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 99/161 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV59836727; called by muse, mutect2, varscan2
- SLC44A2 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59836756; called by muse, varscan2
- SLC4A8 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV60651482, COSV60652356; called by muse, mutect2, varscan2
- SLC5A7 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs748131814, COSV50891645; called by muse, mutect2, varscan2
- SLC6A15 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs1365687664, COSV57023787, COSV57031170; called by muse, mutect2, varscan2
- SLC6A3 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM143023, COSV54361620, COSV54366940; called by muse, mutect2, varscan2
- SLC7A5 | c.377C>G p.S126W | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1041269729, COSV55364473; called by muse, mutect2
- SLC8B1 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV52528097; called by muse, mutect2, varscan2
- SLC9A3 | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 39/116 reads (34%) | catalogued as COSV99375559; called by muse, mutect2, varscan2
- SLC9A9 | c.130C>A p.H44N | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV57227216; called by muse, mutect2, varscan2
- SMCHD1 | c.4813G>C p.E1605Q | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.46); PolyPhen benign (0.115); catalogued as rs1299215590, COSV55257446; called by mutect2, varscan2
- SNRNP40 | c.377C>G p.S126* | Nonsense Mutation (SNP) | VAF 68/154 reads (44%) | catalogued as COSV99744961; called by muse, varscan2
- SP1 | c.2269G>C p.E757Q (on ENST00000327443 / NM_138473.3; = p.E750Q on NM_003109.1) | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV59402886; called by muse, mutect2, varscan2
- SPAG17 | c.2293G>C p.E765Q | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.391); catalogued as COSV60458854; called by muse, mutect2, varscan2
- SPAG9 | c.3620T>C p.I1207T (on ENST00000262013 / NM_001130528.3; = p.I1193T on NM_003971.6) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV56235661; called by muse, mutect2, varscan2
- SPEF2 | c.4879G>C p.D1627H | Missense Mutation (SNP) | VAF 92/260 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57429197; called by muse, mutect2, varscan2
- SPEN | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs139125517; called by muse, varscan2
- SPEN | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65361818; called by muse, varscan2
- SPG7 | c.377-1G>A p.X126_splice | Splice Site (SNP) | VAF 12/20 reads (60%) | catalogued as COSV51950550; called by muse, varscan2
- SPG7 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.094); catalogued as COSV51950587, COSV51953445; called by muse, varscan2
- SPON1 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.207); catalogued as rs372189449; called by muse, mutect2, varscan2
- SPPL2A | c.1470G>C p.W490C | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55941121; called by muse, mutect2, varscan2
- SPSB2 | c.144G>A p.W48* | Nonsense Mutation (SNP) | VAF 53/142 reads (37%) | catalogued as COSV99222759; called by muse, mutect2, varscan2
- SRGAP1 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV61898066; called by muse, mutect2, varscan2
- SRSF2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV57969999; called by muse, mutect2, varscan2
- ST3GAL6 | c.754C>G p.Q252E | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54581271; called by muse, mutect2, varscan2
- ST8SIA6 | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV101112221, COSV66468360; called by muse, mutect2, varscan2
- STAG1 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV52607404, COSV52609972; called by muse, mutect2, varscan2
- STAT1 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV63116116; called by muse, mutect2, varscan2
- STK11IP | c.2290C>G p.Q764E | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV55249266; called by muse, mutect2, varscan2
- STKLD1 | c.810C>A p.F270L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.12); catalogued as COSV64312681; called by muse, mutect2, varscan2
- SUCLG1 | c.1004C>A p.T335K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as COSV67265152; called by muse, mutect2, varscan2
- SUFU | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV64014836; called by muse, mutect2, varscan2
- SUPT20H | c.927G>C p.E309D (on ENST00000350612 / NM_001014286.3; = p.E310D on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.224); catalogued as COSV62247911; called by muse, mutect2, varscan2
- SYN1 | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99901253; called by muse, mutect2
- SYNE3 | c.1686G>T p.R562S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV62079427; called by muse, mutect2, varscan2
- SYNPO2L | c.2029C>G p.L677V (on ENST00000394810 / NM_001114133.3; = p.L453V on NM_024875.5) | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV65736927; called by muse, mutect2, varscan2
- SYP | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV54295181; called by muse, mutect2, varscan2
- TACC2 | c.8414C>G p.S2805* (on ENST00000334433; = p.S883* on NM_006997.4) | Nonsense Mutation (SNP) | VAF 15/112 reads (13%) | catalogued as COSV99586403; called by muse, mutect2, varscan2
- TAF11 | c.561G>T p.M187I | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV51954413, COSV51956619, COSV99511305; called by mutect2, varscan2
- TAF1B | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV55154416, COSV55156165; called by muse, mutect2, varscan2
- TANC1 | c.3223G>A p.D1075N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1037520349, COSV55088136; called by muse, mutect2, varscan2
- TANGO6 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55765532; called by muse, mutect2, varscan2
- TBC1D10A | c.1020G>C p.K340N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV53164241; called by muse, mutect2, varscan2
- TBC1D8B | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV52178859; called by muse, mutect2, varscan2
- TBCD | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62800990; called by muse, mutect2, varscan2
- TBCE | c.1225C>G p.Q409E (on ENST00000366601; = p.Q472E on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV64003601; called by muse, varscan2
- TBCE | c.1255C>T p.L419F (on ENST00000366601; = p.L482F on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.779); catalogued as COSV64003919; called by muse, varscan2
- TBR1 | c.109C>T p.H37Y | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV67417828; called by muse, mutect2, varscan2
- TBX1 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.012); catalogued as COSV61548512; called by muse, mutect2, varscan2
- TCF12 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51006298; called by muse, mutect2, varscan2
- TCF3 | c.1626G>C p.Q542H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV53648507; called by muse, mutect2, varscan2
- TCF4 | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61896759; called by muse, mutect2, varscan2
- TCHH | c.5578G>C p.E1860Q | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV64274794; called by muse, mutect2, varscan2
- TDRD1 | c.2470C>T p.Q824* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV52590484; called by muse, mutect2, varscan2
- TDRKH | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV64316109; called by muse, mutect2, varscan2
- TECPR2 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV63970580; called by muse, mutect2, varscan2
- TECRL | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV67087127; called by muse, mutect2, varscan2
- TECTA | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.167); catalogued as rs1205822683, COSV50707980, COSV50749053; called by muse, mutect2, varscan2
- TET2 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV54411055, COSV54422740; called by muse, mutect2, varscan2
- TFEB | c.632C>A p.S211Y | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57825006, COSV57825308; called by muse, mutect2, varscan2
- TFPT | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV58085317; called by muse, mutect2, varscan2
- TGFBRAP1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV51512178; called by muse, mutect2, varscan2
- TGIF2 | c.140C>G p.S47* | Nonsense Mutation (SNP) | VAF 46/115 reads (40%) | catalogued as COSV100872254, COSV100872284; called by muse, mutect2, varscan2
- TH | c.1306G>A p.E436K (on ENST00000381178 / NM_199292.3; = p.E405K on NM_000360.4) | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as COSV51747140; called by muse, mutect2, varscan2
- THOC2 | c.3682+1G>C p.X1228_splice | Splice Site (SNP) | VAF 13/92 reads (14%) | catalogued as COSV55545964; called by muse, mutect2, varscan2
- THOC2 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55545976; called by muse, mutect2, varscan2
- THOP1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.366); catalogued as COSV57018712; called by muse, mutect2, varscan2
- TIAM1 | c.1049C>G p.S350C | Missense Mutation (SNP) | VAF 45/298 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV54551122; called by muse, mutect2, varscan2
- TIAM2 | c.2113G>C p.E705Q | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59694318; called by muse, mutect2, varscan2
- TICRR | c.3161G>A p.R1054K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as COSV51541523; called by muse, mutect2, varscan2
- TIGAR | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51627844; called by muse, mutect2, varscan2
- TINF2 | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV57468941; called by muse, mutect2, varscan2
- TKFC | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.097); catalogued as rs200053750; called by muse, mutect2, varscan2
- TLK1 | c.2056G>C p.E686Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV62630308; called by muse, mutect2, varscan2
- TM9SF4 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 54/77 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.329); catalogued as COSV54106990; called by muse, varscan2
- TM9SF4 | c.222G>C p.E74D | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV54107008; called by muse, varscan2
- TMCO3 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.656); catalogued as COSV64807581; called by muse, mutect2, varscan2
- TMEM130 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs149015420; called by muse, mutect2, varscan2
- TMEM132A | c.2626C>G p.Q876E (on ENST00000453848 / NM_178031.3; = p.Q877E on NM_017870.4) | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs760593541, COSV50005821; called by muse, mutect2, varscan2
- TMEM132D | c.2366G>C p.G789A | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67160422, COSV67161719; called by muse, mutect2, varscan2
- TMEM51 | c.150G>C p.K50N | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV65691019; called by muse, mutect2, varscan2
- TMPRSS11A | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV58358452; called by muse, mutect2, varscan2
- TMPRSS6 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.307); catalogued as COSV60978203; called by muse, mutect2, varscan2
- TNFRSF11B | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs202090603, COSV52071162; called by muse, mutect2, varscan2
- TNPO2 | c.235C>G p.Q79E | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV63508315; called by muse, mutect2, varscan2
- TOR3A | c.591C>G p.F197L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV61680148, COSV61680359; called by muse, mutect2, varscan2
- TP53BP2 | c.1190C>A p.P397H (on ENST00000343537 / NM_001031685.3; = p.P268H on NM_005426.2) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59068583; called by muse, mutect2, varscan2
- TPP2 | c.3135G>C p.L1045F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65752635; called by muse, mutect2, varscan2
- TRA2A | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.127); catalogued as COSV51716881; called by muse, mutect2, varscan2
- TRIT1 | c.1280G>A p.R427K | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57548284; called by muse, mutect2, varscan2
- TSGA13 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.037); catalogued as COSV58405221; called by muse, mutect2, varscan2
- TTC13 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.34); catalogued as COSV64167813; called by muse, mutect2, varscan2
- TTC3 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.897); catalogued as COSV61290230; called by muse, mutect2, varscan2
- TTC30B | c.1335G>C p.K445N | Missense Mutation (SNP) | VAF 34/402 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV68809301, COSV68809456; called by muse, mutect2
- TTC32 | c.138G>C p.E46D | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV61267643; called by muse, mutect2, varscan2
- TTC39A | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV52958003; called by muse, mutect2, varscan2
- TTLL8 | c.1218C>G p.F406L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99837861; called by muse, varscan2
- TTN | c.87161C>T p.S29054F (on ENST00000591111; = p.S21630F on NM_003319.4) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | PolyPhen probably damaging (0.998); catalogued as COSV60061885; called by muse, mutect2, varscan2
- TTN | c.73853T>G p.I24618S (on ENST00000591111; = p.I17194S on NM_003319.4) | Missense Mutation (SNP) | VAF 32/194 reads (16%) | PolyPhen benign (0.007); catalogued as COSV60061927; called by muse, mutect2, varscan2
- TTN | c.47716G>T p.E15906* (on ENST00000591111; = p.E8482* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as COSV100589324, COSV60176889; called by muse, mutect2, varscan2
- TTN | c.26021C>G p.S8674* (on ENST00000591111; = p.S7747* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100589325; called by muse, mutect2, varscan2
- TTN | c.15107G>A p.R5036Q (on ENST00000591111; = p.R4109Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/27 reads (74%) | PolyPhen possibly damaging (0.873); catalogued as rs751653047, COSV60061976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.15019G>A p.E5007K (on ENST00000591111; = p.E4080K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | PolyPhen possibly damaging (0.654); catalogued as COSV60061989; called by muse, mutect2, varscan2
- TUBA3D | c.330C>G p.I110M | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV58311702; called by mutect2, varscan2
- TUBA3E | c.330C>G p.I110M | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV99919591; called by muse, mutect2, varscan2
- UBAP1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as COSV52658899; called by muse, mutect2, varscan2
- UBE4A | c.2511G>C p.Q837H (on ENST00000252108 / NM_001204077.2; = p.Q844H on NM_004788.4) | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52804216; called by muse, mutect2, varscan2
- UBE4A | c.2822C>G p.P941R (on ENST00000252108 / NM_001204077.2; = p.P948R on NM_004788.4) | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.509); catalogued as COSV52804225; called by muse, mutect2, varscan2
- UBN1 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as COSV52168104; called by muse, mutect2, varscan2
- UBR3 | c.5215G>C p.E1739Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.146); catalogued as COSV55849543, COSV99774339; called by muse, mutect2, varscan2
- UBR4 | c.1688C>T p.S563F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.962); catalogued as COSV64389642; called by muse, mutect2, varscan2
- UGT2A3 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV52359960; called by muse, mutect2, varscan2
- UGT2B17 | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58501487; called by muse, mutect2, varscan2
- UGT2B28 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV59430867, COSV59432001; called by muse, mutect2, varscan2
- USP25 | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53484365; called by muse, mutect2, varscan2
- USP45 | c.2226G>C p.M742I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59680623; called by muse, mutect2, varscan2
- UTP20 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV55377076; called by muse, mutect2, varscan2
- VKORC1L1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.771); catalogued as rs193921078, COSV62488330, COSV62489066; called by muse, mutect2, varscan2
- VNN3 | c.788A>G p.Y263C | Missense Mutation (SNP) | VAF 63/115 reads (55%) | catalogued as COSV51591010; called by muse, mutect2, varscan2
- VPS25 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs754987895, COSV53820660; called by mutect2, varscan2
- VSIG8 | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV63652903; called by mutect2, varscan2
- VSTM2A | c.266G>C p.R89T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.419); catalogued as COSV100173417, COSV56494075; called by muse, mutect2, varscan2
- WASF3 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV58964581; called by muse, mutect2, varscan2
- WDFY3 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs957042356, COSV55700981; called by muse, mutect2, varscan2
- WDR6 | c.3106G>C p.E1036Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV58245002; called by muse, mutect2, varscan2
- WEE1 | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | catalogued as COSV55198091; called by muse, mutect2, varscan2
- WIZ | c.5524G>C p.E1842Q (on ENST00000673675 / NM_001371589.1; = p.E747Q on NM_021241.3) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.881); catalogued as COSV54607495; called by muse, mutect2, varscan2
- WNK3 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV63613930; called by muse, mutect2, varscan2
- XIRP2 | c.3171G>C p.Q1057H (on ENST00000628543; = p.Q1232H on NM_152381.6) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1385894580, COSV54700426; called by muse, mutect2, varscan2
- XKRX | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60707970; called by muse, mutect2, varscan2
- XPOT | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.241); catalogued as COSV60345410; called by muse, mutect2, varscan2
- YEATS2 | c.2483G>A p.G828E | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV59365395; called by muse, mutect2, varscan2
- ZBTB18 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV62396990, COSV62397970; called by muse, mutect2, varscan2
- ZBTB33 | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV58533956; called by muse, mutect2, varscan2
- ZBTB33 | c.1109C>G p.S370* | Nonsense Mutation (SNP) | VAF 50/169 reads (30%) | catalogued as COSV100434024; called by muse, mutect2, varscan2
- ZC3H14 | c.1966C>G p.H656D | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51769566; called by muse, mutect2, varscan2
- ZC3H7A | c.185del p.S62* | Frame Shift Del (DEL) | VAF 25/140 reads (18%) | catalogued as COSV100865627, COSV63269633, COSV63271105; called by mutect2, pindel, varscan2
- ZFHX4 | c.3691C>G p.R1231G | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50799437; called by muse, mutect2, varscan2
- ZFYVE9 | c.3283C>T p.R1095W | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55091516; called by muse, mutect2, varscan2
- ZIC1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51551513; called by muse, mutect2, varscan2
- ZMPSTE24 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.109); catalogued as COSV65638712, COSV65639357; called by muse, varscan2
- ZMPSTE24 | c.773C>G p.S258C | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65639358; called by muse, mutect2, varscan2
- ZMYM3 | c.763G>C p.D255H | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.215); catalogued as COSV58737893; called by muse, mutect2, varscan2
- ZNF107 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV61328674; called by muse, mutect2, varscan2
- ZNF17 | c.16G>C p.D6H | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV56921392; called by muse, mutect2, varscan2
- ZNF174 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51902650, COSV51904576; called by muse, mutect2, varscan2
- ZNF217 | c.2602C>G p.P868A | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV56597167; called by muse, mutect2, varscan2
- ZNF229 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.234); catalogued as COSV52161882; called by muse, mutect2, varscan2
- ZNF280A | c.473G>A p.R158K | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as rs776973246, COSV57480533; called by muse, mutect2, varscan2
- ZNF324B | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV60740652, COSV60741806; called by muse, mutect2, varscan2
- ZNF394 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 57/99 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58742821; called by muse, mutect2, varscan2
- ZNF438 | c.611G>C p.R204T | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV59195151; called by muse, mutect2, varscan2
- ZNF460 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV64415716; called by muse, mutect2, varscan2
- ZNF480 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV57996193; called by muse, mutect2, varscan2
- ZNF493 | c.365C>G p.S122* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100828500; called by muse, mutect2, varscan2
- ZNF526 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV56629798, COSV56631245; called by muse, mutect2, varscan2
- ZNF532 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60173084; called by muse, mutect2, varscan2
- ZNF532 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV60173093; called by muse, mutect2, varscan2
- ZNF543 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58627332, COSV58627459; called by muse, mutect2, varscan2
- ZNF546 | c.366G>C p.M122I | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV61257948; called by muse, mutect2, varscan2
- ZNF556 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.562); catalogued as rs1299982376, COSV56912215; called by muse, mutect2, varscan2
- ZNF557 | c.871G>C p.G291R (on ENST00000414706 / NM_001044388.2; = p.G298R on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV53273854; called by muse, varscan2
- ZNF557 | c.928G>A p.E310K (on ENST00000414706 / NM_001044388.2; = p.E317K on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV53273865; called by muse, varscan2
- ZNF559 | c.710G>C p.G237A | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.088); catalogued as COSV57835606; called by muse, mutect2, varscan2
- ZNF582 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV56732113, COSV56732215; called by muse, mutect2, varscan2
- ZNF7 | c.1314G>C p.E438D | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV57383677; called by muse, mutect2, varscan2
- ZNF703 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV58998634; called by muse, mutect2, varscan2
- ZNF761 | c.357G>C p.L119F | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.22); catalogued as COSV61888353; called by muse, mutect2, varscan2
- ZNF791 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100588990; called by muse, mutect2, varscan2
- ZNF800 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV56175698; called by muse, mutect2, varscan2
- ZNF813 | c.804G>C p.E268D | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV67176525; called by muse, mutect2, varscan2
- ZNF816 | c.72G>C p.L24F | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54411198; called by muse, mutect2, varscan2
- ZNF830 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.038); catalogued as COSV58489198; called by muse, mutect2, varscan2
- ZNF839 | c.466C>G p.L156V (on ENST00000558850 / NM_001267827.1; = p.L272V on NM_018335.5) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99215972; called by muse, mutect2
- ZNF875 | c.1871G>C p.R624T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.105); catalogued as COSV60991284; called by muse, mutect2, varscan2
- ZNHIT1 | c.120C>G p.F40L | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV59312878, COSV59313208; called by muse, mutect2, varscan2
- ZSCAN18 | c.261G>C p.Q87H | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53733081; called by muse, mutect2, varscan2
- ZSCAN29 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV53019115; called by muse, mutect2, varscan2
322 further variants in this file (13 protein-altering or splice-affecting, 281 silent, 28 other) are not listed here.
